Surgical pathology report (de-identified scan), TCGA case TCGA-N9-A4Q1, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MD Anderson, specimen TCGA-N9-A4Q1-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

DIAGNOSIS

(A) UTERUS, CERVIX, RIGHT FALLOPIAN TUBE, AND RIGHT OVARY:

UTERUS, MALIGNANT MIXED MULLERIAN TUMOR. (SEE COMMENT)

TUMOR INVOLVES ANTERIOR AND POSTERIOR CERVICAL GLANDS AND STROMA, WITH MAXIMAL

CERVICAL INVASION OF 15 MM (CERVICAL THICKNESS 18 MM).

TUMOR INVADES MYOMETRIUM TO A DEPTH OF 17 MM (MYOMETRIAL THICKNESS 29 MM).

SARCOMATOUS COMPONENT ARISES FROM ENDOMETRIAL POLYP.

Lymphovascular invasion present.

Myometrium, leiomyomata.

Right ovary: No tumor present.

Right fallopian tube: Mild epithelial hyperplasia.

Left fallopian tube: Paratubal cyst.

(B) TISSUE DESIGNATED "ADDITIONAL RIGHT VAGINAL MARGIN":

Squamous mucosa, no tumor present.

(C) OMENTUM, BIOPSY:

Adipose tissue, no tumor present.

(D) LEFT PELVIC LYMPH NODES:

Two lymph nodes, no tumor present (0/2).

(E) LEFT OBTURATOR LYMPH NODE:

One lymph node, no tumor present (0/1).

(F) LEFT COMMON ILIAC LYMPH NODE:

One lymph node, no tumor present (0/1).

(G) LEFT PARA-AORTIC LYMPH NODE:

One lymph node, no tumor present (0/1).

(H) LEFT HIGH PARA-AORTIC LYMPH NODE:

One lymph node, no tumor present (0/1).

(I) RIGHT PARA-AORTIC LYMPH NODE:

Two lymph nodes, endosalpingiosis.

(J) LEFT PELVIC LYMPH NODES:

Three lymph nodes, no tumor present (0/3).

ICD -O-3
Mixed Mullerian Tumor 8950/3
Site: uterus, NOS CSS. 9
copied AWS 1/16/13

Entire report and diagnosis completed by

COMMENT

The carcinomatous component of the malignant mixed mullerian tumor is composed predominantly of high-grade endometrioid carcinoma with sex cord-like differentiation and focal papillary serous carcinoma. The stromal component consists predominantly of unclassified high-grade sarcoma with foci of cartilaginous differentiation.

GROSS DESCRIPTION

(A) UTERUS, CERVIX, BILATERAL TUBES AND OVARIES - A uterus (14.0 x 7.0 x 6.0 cm) with attached right fallopian tube (7. cm in length and 0.5 to 1.0 cm in diameter), and right ovary (3.0 x 2.0 x 1.5 cm), left fallopian tube stump (0.5 cm in length and 0.5 cm in diameter). The left ovary is not identified.

[page 2 of 3]
A mass (11.0 x 6.0 x 6.0 cm) is identified in the uterus involving anterior and left lateral wall of mid, lower uterine segment and upper endocervical canal. The main mass has the connection to a polypoid mass, which is attached to the most superior part of the fundus. The mass is 1.5 cm to the exocervix. The mass invades into the wall at endocervical canal and 0.3 cm from the deep margin, invades into the lower uterine segment and 0.6 cm to the deep resection margin. At the mid uterine segment, the mass involving 1.0 cm of the myometrium. The myometrial thickness is 2.0 cm. The endometrium between the mass is unremarkable. Multiple leiomyomas (1.2 to 2.0 cm in diameter) is identified in the myometrium. The cut surface of those nodules have no hemorrhage or necrosis.

The ovary and fallopian tube are unremarkable. A parovarian cyst (1.0 cm in diameter) is present.

Note: The surgeon indicated that only right side of tube and ovary were taken.

INK CODE: Blue - deep margin at the cervix, yellow - section cut, not margin.

SECTION CODE: A1, A2, anterior exocervix and mass; A3, A4, anterior endocervix and tumor including deep margin; A5 anterior lower uterine segment tumor, including deep margin; A6, A7, mid uterine segment with tumor, full-thickness (yellow inked at the cut surface); A8, A9, posterior exocervix with tumor; A10, posterior endocervical canal with tumor including deep margin; A11, A12, posterior lower uterine segment with tumor including deep margin; A13, A14, posterior uterine segment, full-thickness; A15, section between the mass and polypoid lesion with normal-appearing endometrium; A16, A17, polypoid mass attached area at superior aspect of the fundus; A18-A26, representative sections of tumor; A27, A28, representative sections of leiomyomas; A29, right ovary and parovarian cyst; A30, right fallopian tube; A31, left fallopian tube stump.

(B) ADDITIONAL RIGHT VAGINAL MARGIN - A segment of vagina (4.5 x 1.0 x 0.5 cm). One edge of the vaginal wall is inked in blue, the other edge is inked in yellow and submitted entirely in B1 and B2 with both edges of en face.

(C) OMENTUM BIOPSY - A segment of adipose tissue (8.0 x 6.0 x 2.0 cm). Sections reveal no gross identifiable lesion.

Representative sections are submitted in C1-C6.

(D) LEFT PELVIC LYMPH NODE - Two lymph nodes (1.0 x 0.8 x 0.5 and 2.5 x 1.0 x 0.5 cm).

SECTION CODE: D1, one lymph node bisected; D2, one lymph node bisected.

(E) LEFT OBTURATOR LYMPH NODE - A 1.3 x 0.9 x 0.5 cm fragmented lymph node totally submitted for frozen section in E.

*FS/DX: NEGATIVE FOR TUMOR.

(F) LEFT COMMON ILIAC LYMPH NODE - A single lymph node (1.5 x 1.0 x 0.8 cm). The specimen is bisected and entirely submitted in F.

(G) LEFT PARA-AORTIC LYMPH NODE - A single lymph node (1.5 x 1.0 x 0.8 cm). The specimen is bisected and entirely submitted in G.

(H) LEFT PARA-AORTIC LYMPH NODE - A single lymph node (6.0 x 1.5 x 1.5 cm). The specimen is serially sectioned and entirely submitted in H1-H6.

(I) RIGHT PARA-AORTIC LYMPH NODE - Two lymph nodes (0.4 x 0.3 x 0.2 cm and 1.5 x 0.8 x 0.4 cm). Toto in I.

(J) LEFT PELVIC LYMPH NODE - Three lymph nodes ranging from 1.0 x 1.0 x 0.5 to 2.0 x 1.0 x 0.5 cm.

SECTION CODE: J1, one lymph node bisected; J2, one lymph node bisected; J3, one lymph node bisected.

CLINICAL HISTORY

Uterine cancer.

SNOMED CODES

T-83020, M-89503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

[page 3 of 3]
Preliminary: 10/10/12 LW

Source: NCI Genomic Data Commons file a37c4ce7-13cf-410e-b98c-54faa92aeb89 (TCGA-N9-A4Q1.C51B6612-4221-4214-AADE-FDDD8A7C5BF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).